Somatic mutation profile of tumor specimen 0DIW7U from CCDI case PBBWFG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.7 years (2,830 days).
Specimen 0DIW7U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a61d9b-009c-4628-947a-36db8d83dbb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW6A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e3f346b-ec6f-4e0f-9f49-92ab43dd50fd

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 3'UTR 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 246/729 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 353/872 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs397507541, CM041072, COSV61005566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCORL1 | c.1929del p.M644Cfs*4 | Frame Shift Del (DEL) | VAF 172/436 reads (39%) | catalogued as rs1229639561; called by mutect2, varscan2
- C9orf72 | c.1385_1386del p.F462Yfs*9 | Frame Shift Del (DEL) | VAF 534/1368 reads (39%) | catalogued as rs753188234; called by mutect2, varscan2
- CFHR4 | c.542G>T p.S181I (on ENST00000367416 / NM_001201551.2; = p.S182I on NM_001201550.3) | Missense Mutation (SNP) | VAF 533/1131 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs970459942; called by muse, mutect2, varscan2
- DENND2C | c.1771T>A p.Y591N (on ENST00000393274 / NM_001256404.2; = p.Y534N on NM_198459.4) | Missense Mutation (SNP) | VAF 411/988 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV67921629; called by muse, mutect2, varscan2
- KCTD19 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 32/1074 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs943861945, COSV58571682; called by muse, mutect2
- NLRP5 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 239/547 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376992928; called by muse, mutect2, varscan2
- SLC12A7 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 675/821 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs372638882; called by muse, mutect2, varscan2
- TP53 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 256/526 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); catalogued as rs137852789, CD090894, COSV52728772, COSV52825108, COSV53596858; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- USH2A | c.8942C>T p.S2981F | Missense Mutation (SNP) | VAF 654/1370 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1166862111; called by muse, mutect2, varscan2
- CHD9 | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 357/827 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HUWE1 | c.6668A>G p.N2223S | Missense Mutation (SNP) | VAF 307/770 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP1B2 | c.405C>T p.Y135= | Silent (SNP) | VAF 65/712 reads (9%) | catalogued as rs1209948984, COSV51516117; called by muse, mutect2
- BPIFB6 | c.939C>G p.T313= | Silent (SNP) | VAF 303/671 reads (45%) | called by muse, mutect2, varscan2
- NLRP4 | c.1251C>T p.D417= | Silent (SNP) | VAF 146/311 reads (47%) | catalogued as rs376218682, COSV56714165; called by muse, mutect2, varscan2
- ZHX3 | c.1353C>T p.P451= | Silent (SNP) | VAF 32/861 reads (4%) | catalogued as rs1304906269; called by muse, mutect2
- IFITM1 | c.*95G>C | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- SEM1 | c.*86dup | 3'UTR (INS) | VAF 190/423 reads (45%) | catalogued as rs1448801462; called by mutect2, varscan2
- SON | c.6321+266C>T | Intron (SNP) | VAF 395/951 reads (42%) | catalogued as rs774399367; called by muse, mutect2, varscan2
